Somatic mutation profile of tumor specimen TCGA-DQ-7588-01A (aliquot TCGA-DQ-7588-01A-11D-2078-08) from TCGA case TCGA-DQ-7588, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Tumor grade: G3; Age at diagnosis: 66.0 years (24,106 days).
Specimen TCGA-DQ-7588-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 309c998a-79de-4f37-9452-78495ebb3f09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-7588-10B (Blood Derived Normal), aliquot TCGA-DQ-7588-10B-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c45065ef-eaa9-45ca-89fb-1f7095403d45

The open-access MAF lists 109 somatic variants for this specimen: 82 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 24, Nonsense Mutation 9, Frame Shift Del 6, RNA 2, Splice Site 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV50285556; called by muse, mutect2, varscan2
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- AASDH | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99220725; called by muse, mutect2, varscan2
- ABCA9 | c.257C>G p.T86S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV100382563; called by muse, mutect2, varscan2
- ABCC10 | c.3311A>G p.Y1104C (on ENST00000372530 / NM_001198934.2; = p.Y1076C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778932887, COSV99766547; called by muse, mutect2, varscan2
- ABCG8 | c.1841A>T p.K614I | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.052); catalogued as COSV99699401; called by muse, mutect2
- ACTBL2 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV101379221; called by muse, mutect2, varscan2
- ACY3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV99662873; called by muse, mutect2, varscan2
- ADAM33 | c.621G>T p.R207S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as COSV100597665; called by muse, mutect2, varscan2
- AHNAK | c.8431A>G p.I2811V | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV99945390; called by muse, mutect2, varscan2
- AJUBA | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 54/75 reads (72%) | catalogued as rs767437060, COSV52984456; called by muse, mutect2, varscan2
- AKAP10 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99855234; called by muse, mutect2, varscan2
- APP | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV100695218; called by muse, mutect2, varscan2
- ARHGEF26 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100726371, COSV62846065; called by muse, mutect2, varscan2
- BLK | c.620-1G>C p.X207_splice | Splice Site (SNP) | VAF 47/126 reads (37%) | catalogued as COSV99376810; called by muse, mutect2, varscan2
- CACNG1 | c.290T>A p.F97Y | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.378); catalogued as rs1177589696, COSV99871592; called by muse, mutect2, varscan2
- CAMK1D | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as rs1200525794, COSV101123397; called by muse, mutect2, varscan2
- CARF | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV100247463; called by muse, mutect2, varscan2
- CECR2 | c.2242C>T p.Q748* (on ENST00000342247 / NM_001290047.2; = p.Q565* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99376875; called by muse, mutect2, varscan2
- CNOT6 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99993380; called by muse, mutect2, varscan2
- CNOT6L | c.1570C>T p.H524Y (on ENST00000504123 / NM_001286790.2; = p.H519Y on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV99361254; called by muse, mutect2, varscan2
- COPA | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs1051839166, COSV54105294; called by muse, mutect2, varscan2
- CSMD3 | c.1728G>C p.W576C (on ENST00000297405 / NM_001363185.1; = p.W472C on NM_052900.3) | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99823322; called by muse, mutect2, varscan2
- DEFB115 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762891282, COSV101269283; called by muse, mutect2, varscan2
- DNMT1 | c.3973C>T p.P1325S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61576450; called by muse, mutect2, varscan2
- DOCK7 | c.3083A>T p.K1028I (on ENST00000635253 / NM_001367561.1; = p.K997I on NM_033407.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV52021164; called by muse, mutect2, varscan2
- EPHB2 | c.2497C>T p.Q833* (on ENST00000400191 / NM_001309193.2; = p.Q834* on NM_004442.7) | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV101006728; called by muse, mutect2, varscan2
- FMR1 | c.870G>T p.R290S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99502905; called by muse, mutect2
- GBP1 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100976211; called by muse, mutect2, varscan2
- GFRAL | c.774C>A p.C258* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100474473; called by muse, mutect2, varscan2
- GRID2 | c.1813C>G p.L605V | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772086434, COSV99936853; called by muse, mutect2, varscan2
- GUCY2F | c.2187T>G p.F729L | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as rs113612238, COSV99484443; called by muse, mutect2, varscan2
- GUF1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99876981; called by muse, mutect2, varscan2
- HAVCR1 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV100207902; called by muse, mutect2, varscan2
- HDAC9 | c.1407G>C p.Q469H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as COSV101286020; called by muse, varscan2
- HECW2 | c.3146A>T p.D1049V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.905); catalogued as COSV99645692; called by muse, varscan2
- HNRNPA2B1 | c.992A>G p.Y331C (on ENST00000354667 / NM_031243.3; = p.Y319C on NM_002137.4) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs770089393, COSV100668207; called by muse, mutect2, varscan2
- IGKV6D-41 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs750773409; called by muse, mutect2, varscan2
- KALRN | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99561953; called by muse, mutect2, varscan2
- KCNQ1 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99325573; called by muse, mutect2, varscan2
- KLHDC8A | c.459C>A p.D153E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100903779; called by muse, mutect2, varscan2
- KLHL12 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV100766138; called by muse, mutect2, varscan2
- KRT86 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV99524830; called by muse, mutect2, varscan2
- LRIG3 | c.1252A>T p.S418C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100292392; called by muse, mutect2, varscan2
- LZTS1 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763490121, COSV99742601; called by muse, mutect2, varscan2
- MGA | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99578314; called by muse, mutect2, varscan2
- MIA3 | c.2764G>C p.D922H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV100719261; called by muse, mutect2, varscan2
- MTOR | c.6514T>A p.L2172M | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV100815682; called by muse, mutect2, varscan2
- MYH1 | c.4190T>A p.L1397Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99874791; called by muse, mutect2, varscan2
- NRBP1 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 19/154 reads (12%) | catalogued as COSV99274729; called by muse, mutect2, varscan2
- OR6A2 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100215576; called by muse, mutect2, varscan2
- OXSR1 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.557); catalogued as COSV100309112; called by muse, mutect2
- PCDHA2 | c.2252C>G p.S751W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100973528, COSV100973707; called by muse, mutect2, varscan2
- PDE1A | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100112742; called by muse, mutect2, varscan2
- PHLDB2 | c.3072C>G p.I1024M (on ENST00000393925 / NM_001134439.2; = p.I981M on NM_145753.2) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as COSV101208385; called by muse, mutect2
- PIK3CB | c.1326T>A p.N442K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100005180; called by muse, mutect2, varscan2
- PLCG1 | c.2425G>C p.E809Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV54815258, COSV99718437; called by muse, mutect2, varscan2
- PLCXD1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs752401046, COSV101087726; called by muse, mutect2, varscan2
- PLEKHA5 | c.2483C>A p.S828* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100163403, COSV54708945; called by muse, mutect2, varscan2
- PTPN14 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as rs772792425, COSV100872307, COSV65284115; called by muse, mutect2, varscan2
- QRICH2 | c.4741A>G p.T1581A | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV99428753; called by muse, mutect2, varscan2
- RING1 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1562456972, COSV100761713; called by muse, mutect2, varscan2
- SEMA3A | c.674A>T p.K225M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99545091; called by muse, mutect2, varscan2
- SLC30A8 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as COSV101438233; called by muse, mutect2, varscan2
- SMARCC2 | c.913C>G p.P305A | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV57222124, COSV99910735; called by muse, mutect2, varscan2
- SPTY2D1 | c.1417C>G p.H473D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100311474; called by muse, mutect2, varscan2
- STARD6 | c.536T>A p.L179* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100323350; called by muse, mutect2, varscan2
- SYNE2 | c.9076G>C p.E3026Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100646568, COSV59941318; called by muse, mutect2, varscan2
- SYNE2 | c.9300G>C p.E3100D | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100646569; called by muse, mutect2, varscan2
- THSD7B | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775249555, COSV55674045, COSV55742842; called by muse, mutect2, varscan2
- TIMM23 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1410363205; called by muse, mutect2, varscan2
- TNRC6C | c.4358C>A p.T1453K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100049413; called by muse, varscan2
- TTYH2 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV99482780; called by muse, mutect2, varscan2
- USP8 | c.178T>G p.Y60D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100208701; called by muse, mutect2, varscan2
- ZNF99 | c.1183A>C p.K395Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101233673; called by muse, mutect2, varscan2
- IGKV6-21 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IPO8 | c.2834del p.F945Sfs*21 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- LGI3 | c.167_170del p.K56Rfs*13 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- NNAT | c.169_188delinsC p.E57Pfs*18 (on ENST00000649309 / NM_001322802.2; = p.Q58Hfs*68 on NM_005386.4) | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by pindel, varscan2*
- PLSCR4 | c.803del p.G268Afs*31 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | called by mutect2, pindel, varscan2
- SIPA1L3 | c.1786del p.H596Tfs*12 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | called by mutect2, pindel, varscan2
- SLC52A1 | c.904dup p.S302Kfs*198 | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- C11orf54 | c.93C>A p.V31= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV100486943, COSV100487072; called by muse, mutect2, varscan2
- EGR4 | c.1437C>T p.H479= (on ENST00000545030; = p.H376= on NM_001965.4) | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101474202; called by muse, mutect2
- ELAVL4 | c.264G>T p.G88= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs766623314, COSV100836523; called by muse, mutect2, varscan2
- EMID1 | c.546C>A p.P182= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV100468641; called by muse, mutect2, varscan2
- FBXO7 | c.987A>G p.V329= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as rs761014790, COSV99832406; called by muse, mutect2, varscan2
- GART | c.1968C>T p.L656= | Silent (SNP) | VAF 76/111 reads (68%) | catalogued as rs779375144, COSV101111334; called by muse, mutect2, varscan2
- GLG1 | c.2589A>G p.V863= | Silent (SNP) | VAF 69/263 reads (26%) | catalogued as COSV99215222; called by muse, mutect2, varscan2
- IGHV1-46 | c.279G>A p.T93= | Silent (SNP) | VAF 191/244 reads (78%) | catalogued as rs782717921; called by muse, mutect2, varscan2
- LIN7A | c.69C>G p.L23= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99691667; called by muse, mutect2, varscan2
- MED13L | c.2271T>C p.T757= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV99927727; called by muse, mutect2, varscan2
- NR2F2 | c.348C>A p.R116= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV101240908; called by muse, mutect2, varscan2
- NUP93 | c.2436G>A p.V812= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV100359876; called by muse, mutect2, varscan2
- PLPPR2 | c.91C>T p.L31= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99264186, COSV99264822; called by muse, mutect2, varscan2
- PPP1R15A | c.1857C>G p.L619= | Silent (SNP) | VAF 120/275 reads (44%) | catalogued as COSV99565790; called by muse, mutect2, varscan2
- PRKAA1 | c.1131C>T p.F377= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1028768757, COSV99713074; called by muse, varscan2
- RNF40 | c.2454G>A p.K818= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV100221885; called by muse, mutect2, varscan2
- SFRP4 | c.333C>T p.L111= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1007148498, COSV99554203; called by muse, mutect2, varscan2
- SPNS1 | c.792G>A p.L264= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV100208885; called by muse, mutect2, varscan2
- SV2A | c.1356T>A p.G452= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV100974978; called by muse, mutect2, varscan2
- TAS2R19 | c.727C>T p.L243= | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as COSV101114008; called by muse, varscan2
- TEP1 | c.3468G>A p.L1156= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs1195505075, COSV99401566; called by muse, mutect2, varscan2
- USP47 | c.525C>G p.S175= (on ENST00000399455 / NM_001372095.1; = p.S87= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100359128; called by muse, mutect2, varscan2
- ZNF101 | c.954C>G p.V318= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100543451; called by muse, mutect2, varscan2
- ZNF347 | c.1269C>T p.H423= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV61970970; called by muse, mutect2, varscan2
- LINC02870 | n.491G>A | RNA (SNP) | VAF 24/88 reads (27%) | catalogued as rs1457127305; called by muse, mutect2, varscan2
- SNORD115-43 | n.12G>A | RNA (SNP) | VAF 44/361 reads (12%) | called by muse, mutect2, varscan2
- ZNF71 | c.-2A>G | 5'UTR (SNP) | VAF 28/65 reads (43%) | catalogued as COSV100045541; called by muse, mutect2, varscan2
